Somatic mutation profile of tumor specimen C3N-02234-01 (aliquot CPT0214650009) from CPTAC case C3N-02234, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 67.8 years (24,754 days).
Specimen C3N-02234-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc2cf37-f588-487a-bdef-3b6247b7c16b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02234-71 (Blood Derived Normal), aliquot CPT0214770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/50e782da-09e3-42a8-ad1f-5c910ee13ada

The open-access MAF lists 83 somatic variants for this specimen: 65 protein-altering or splice-affecting, 15 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 15, Frame Shift Ins 4, Splice Site 3, In Frame Del 2, Frame Shift Del 2, Intron 1, 3'UTR 1, Nonsense Mutation 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAIAP3 | c.1171-1G>A p.X391_splice | Splice Site (SNP) | VAF 54/407 reads (13%) | catalogued as COSV100182016; called by muse, mutect2, varscan2
- C2CD3 | c.2900A>G p.N967S | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.789); catalogued as rs777109415; called by muse, mutect2
- CRISP1 | c.80G>C p.R27T | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.04); catalogued as rs762528316; called by muse, mutect2
- CSMD3 | c.4078C>G p.P1360A (on ENST00000297405 / NM_001363185.1; = p.P1256A on NM_052900.3) | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99837525; called by muse, mutect2
- DNAH8 | c.11027C>T p.A3676V | Missense Mutation (SNP) | VAF 42/485 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs201922165, COSV100544752; called by muse, mutect2
- EPHB2 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 77/342 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.433); catalogued as rs1445956482; called by muse, mutect2, varscan2
- FGL1 | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67712236; called by muse, mutect2
- FIZ1 | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 54/400 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.602); catalogued as rs771968499; called by muse, mutect2, varscan2
- FUT10 | c.1346A>G p.Q449R | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs1350569202; called by muse, mutect2
- GFRA4 | c.829A>G p.T277A (on ENST00000319242 / NM_145762.3; = p.T247A on NM_022139.4) | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1354364904; called by muse, mutect2, varscan2
- IL4I1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 68/740 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs182795409; called by muse, mutect2
- KLHDC1 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs555237025; called by muse, mutect2, varscan2
- LARP1 | c.2140A>G p.M714V (on ENST00000518297 / NM_033551.3; = p.M637V on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/241 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1233210446; called by muse, mutect2, varscan2
- NAALADL1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs369869196; called by muse, mutect2, varscan2
- NAV1 | c.3405+1G>A p.X1135_splice | Splice Site (SNP) | VAF 30/188 reads (16%) | catalogued as rs1468840285; called by muse, mutect2, varscan2
- NCL | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1468527907, COSV59546970; called by muse, mutect2
- OR10W1 | c.616A>G p.T206A | Missense Mutation (SNP) | VAF 27/274 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV67720361; called by muse, mutect2
- SPNS3 | c.1382dup p.G462Rfs*29 | Frame Shift Ins (INS) | VAF 51/195 reads (26%) | catalogued as rs756918252; called by mutect2, pindel, varscan2
- TAF1L | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 43/322 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs765406541; called by muse, mutect2, varscan2
- TP53 | c.796_797del p.G266Tfs*5 | Frame Shift Del (DEL) | VAF 101/565 reads (18%) | catalogued as COSV52781281, COSV52975168; called by mutect2, pindel, varscan2
- USP34 | c.7687A>G p.I2563V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.558); catalogued as rs748108252; called by muse, mutect2, varscan2
- USP36 | c.3367C>T p.R1123C | Missense Mutation (SNP) | VAF 49/240 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs772083577, COSV61752079; called by muse, mutect2, varscan2
- ZBTB1 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as COSV100704219; called by muse, mutect2
- ABCC6 | c.865C>G p.L289V | Missense Mutation (SNP) | VAF 92/741 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- AP2A1 | c.2238-3C>G | Splice Region (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- ARID2 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- BAP1 | c.1901_1918del p.A634_V639del | In Frame Del (DEL) | VAF 86/650 reads (13%) | called by mutect2, pindel
- CBARP | c.256A>T p.T86S (on ENST00000382477; = p.T92S on NM_152769.3) | Missense Mutation (SNP) | VAF 13/179 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2
- CCDC168 | c.5939A>G p.N1980S | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CCDC39 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2
- CCDC88A | c.3055A>C p.S1019R | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.028); called by muse, mutect2
- CD164 | c.318dup p.D107Rfs*19 | Frame Shift Ins (INS) | VAF 36/190 reads (19%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 26/328 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by muse, mutect2
- ERLEC1 | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- EXTL2 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FAM217B | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- GAD1 | c.502A>G p.I168V | Missense Mutation (SNP) | VAF 39/286 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GAD1 | c.999G>C p.Q333H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.281); called by muse, mutect2
- HSPBAP1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- ILVBL | c.1592_1593del p.F531* | Frame Shift Del (DEL) | VAF 12/110 reads (11%) | called by mutect2, pindel, varscan2
- JARID2 | c.3451-1G>C p.X1151_splice | Splice Site (SNP) | VAF 15/178 reads (8%) | called by muse, mutect2
- KCNK3 | c.922T>C p.S308P | Missense Mutation (SNP) | VAF 34/262 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KCNK5 | c.38dup p.F14Lfs*53 | Frame Shift Ins (INS) | VAF 51/266 reads (19%) | called by mutect2, pindel, varscan2
- LCE5A | c.310A>G p.S104G | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.14); called by muse, mutect2
- LRP1 | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LRRC8D | c.1135dup p.I379Nfs*29 | Frame Shift Ins (INS) | VAF 17/122 reads (14%) | called by mutect2, pindel, varscan2
- LRRK1 | c.4177C>G p.L1393V | Missense Mutation (SNP) | VAF 14/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MBTD1 | c.956A>G p.Y319C | Missense Mutation (SNP) | VAF 56/460 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH9 | c.5124C>A p.D1708E | Missense Mutation (SNP) | VAF 50/612 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.025); called by muse, mutect2
- NDUFA4L2 | c.140_142del p.D47del | In Frame Del (DEL) | VAF 25/95 reads (26%) | called by mutect2, pindel, varscan2
- NKIRAS2 | c.449C>T p.S150L | Missense Mutation (SNP) | VAF 48/472 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- NWD1 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.025); called by muse, mutect2
- OSBP | c.1643A>C p.K548T | Missense Mutation (SNP) | VAF 18/320 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC38A9 | c.1494C>G p.F498L | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.046); called by muse, mutect2
- SLC9A9 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- SRPK1 | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SYNE2 | c.1499C>G p.S500* | Nonsense Mutation (SNP) | VAF 48/312 reads (15%) | called by muse, mutect2, varscan2
- TCIRG1 | c.2461A>C p.S821R | Missense Mutation (SNP) | VAF 76/645 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- TET3 | c.3986G>A p.S1329N | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- THSD7A | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 49/447 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDCP | c.1522G>T p.D508Y | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- ZDHHC20 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZFHX4 | c.3365T>C p.L1122P | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ZNF677 | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- ZNF680 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 15/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFAP47 | c.1338G>A p.T446= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs373129355, COSV52883737, COSV52883923; called by muse, mutect2, varscan2
- COL18A1 | c.3246C>T p.L1082= (on ENST00000359759 / NM_130444.3; = p.L847= on NM_030582.4) | Silent (SNP) | VAF 38/474 reads (8%) | catalogued as rs1304073582; called by muse, mutect2
- EPB42 | c.1005G>A p.T335= (on ENST00000441366 / NM_001114134.2; = p.T365= on NM_000119.3) | Silent (SNP) | VAF 54/599 reads (9%) | catalogued as rs1160902890; called by muse, mutect2
- HERC2 | c.2028C>T p.G676= | Silent (SNP) | VAF 26/198 reads (13%) | called by muse, mutect2, varscan2
- HSD17B1 | c.255G>T p.V85= | Silent (SNP) | VAF 64/651 reads (10%) | called by muse, mutect2, varscan2
- MYOCD | c.1923G>T p.G641= | Silent (SNP) | VAF 30/128 reads (23%) | called by muse, mutect2, varscan2
- NPAS1 | c.96G>A p.L32= | Silent (SNP) | VAF 18/172 reads (10%) | called by muse, mutect2, varscan2
- OPA1 | c.975A>G p.E325= (on ENST00000361510 / NM_130837.3; = p.E270= on NM_015560.3) | Silent (SNP) | VAF 18/162 reads (11%) | called by muse, mutect2, varscan2
- OSBPL5 | c.2085G>A p.L695= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs760831817; called by muse, mutect2
- PTCD3 | c.651A>G p.A217= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- RGS19 | c.282G>A p.L94= | Silent (SNP) | VAF 16/324 reads (5%) | called by muse, mutect2
- SLC39A4 | c.1890C>T p.G630= (on ENST00000301305 / NM_001374839.1; = p.G605= on NM_017767.3) | Silent (SNP) | VAF 64/702 reads (9%) | catalogued as rs1048588193, COSV52778202; called by muse, mutect2
- TNIP3 | c.465C>T p.Y155= | Silent (SNP) | VAF 16/318 reads (5%) | catalogued as rs552541016, COSV50252747; called by muse, mutect2
- TUT7 | c.4437A>G p.K1479= | Silent (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- ZNF148 | c.2166A>G p.Q722= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as rs974000089; called by muse, mutect2, varscan2
- FRMD8P1 | n.484G>T | RNA (SNP) | VAF 69/370 reads (19%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-1425C>T | Intron (SNP) | VAF 17/174 reads (10%) | catalogued as rs377226424; called by muse, mutect2
- PWWP2A | c.*32A>G | 3'UTR (SNP) | VAF 30/159 reads (19%) | catalogued as rs372123171; called by muse, mutect2, varscan2
